Somatic mutation profile of tumor specimen TCGA-EI-6882-01A (aliquot TCGA-EI-6882-01A-11D-1924-10) from TCGA case TCGA-EI-6882, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.4 years (21,682 days).
Specimen TCGA-EI-6882-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c81f923-ea1f-41b4-94cb-d8d39c244536.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EI-6882-10A (Blood Derived Normal), aliquot TCGA-EI-6882-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30f77f52-2b2f-42da-a354-910494f61919

The open-access MAF lists 1,461 somatic variants for this specimen: 1,086 protein-altering or splice-affecting, 349 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 820, Silent 349, Frame Shift Del 151, Nonsense Mutation 43, Frame Shift Ins 42, Splice Site 16, Intron 12, Splice Region 8, RNA 5, In Frame Del 5, 3'Flank 2, 5'UTR 2.

Variants (750 of 1,461; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADVL | c.1316del p.G439Vfs*5 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as rs748077880; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACTA2 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 17/148 reads (11%) | catalogued as rs886038978, CM118493, COSV56516891; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAR | c.2675G>A p.R892H | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398122892, CM070004, CM129810, COSV52716474; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 25/63 reads (40%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.4473dup p.A1492Cfs*22 | Frame Shift Ins (INS) | VAF 34/104 reads (33%) | catalogued as rs398123122, COSV57345867, COSV99964369, COSV99971373; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATM | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 77/158 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs202160435, COSV53723910, COSV53729033; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- B4GALT7 | c.277del p.H93Tfs*27 | Frame Shift Del (DEL) | VAF 26/126 reads (21%) | catalogued as rs879255634; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 30/62 reads (48%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRCA2 | c.4169dup p.L1390Ffs*13 | Frame Shift Ins (INS) | VAF 15/123 reads (12%) | catalogued as rs80359433; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRCA2 | c.5073dup p.W1692Mfs*3 | Frame Shift Ins (INS) | VAF 40/120 reads (33%) | catalogued as rs80359479; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- COQ8A | c.1228C>T p.R410* | Nonsense Mutation (SNP) | VAF 16/96 reads (17%) | catalogued as rs753254213, CM1314391, COSV64658043; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 32/63 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GBA | c.1342G>C p.D448H | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as rs1064651, CM900106; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GCDH | c.1173del p.N392Mfs*9 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs754002357; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- JAG1 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918351, CM981095, CM992632, COSV54757968; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNJ2 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 149/379 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199473368, CM070956, COSV54662288; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 69/135 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MECP2 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28934906, CM992178, COSV57651729; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OTUD6B | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as rs368313959, COSV53443535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PAX5 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 20/49 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs926053251, COSV63904854, COSV63909409; called by muse, mutect2, varscan2
- PRKCI | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 68/171 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV55519623; called by muse, mutect2, varscan2
- SLC12A3 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775931992, CM014400, COSV52635778; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPR | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as rs779204655, CM123176, COSV52297859; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 49/102 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- A2M | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs773505902, COSV59384565; called by muse, mutect2, varscan2
- AASS | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV62790393; called by muse, mutect2, varscan2
- AASS | c.484A>G p.I162V | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV62790396; called by muse, mutect2, varscan2
- ABCA13 | c.12685G>A p.D4229N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.023); catalogued as rs1397988590, COSV68947628; called by muse, mutect2, varscan2
- ABCA4 | c.3347C>A p.S1116Y | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64674267; called by muse, mutect2, varscan2
- ABCB5 | c.2276G>T p.R759I (on ENST00000404938 / NM_001163941.2; = p.R314I on NM_178559.6) | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.692); catalogued as COSV51703345, COSV51711677; called by muse, mutect2, varscan2
- ABCB6 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs145498806; called by muse, mutect2, varscan2
- ABCB9 | c.1672del p.L558Wfs*24 (on ENST00000280560 / NM_019625.4; = p.L515Wfs*24 on NM_019624.3) | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as rs1334723787; called by mutect2, pindel, varscan2
- ABCC10 | c.704G>A p.R235H (on ENST00000372530 / NM_001198934.2; = p.R192H on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); catalogued as rs200394501; called by muse, mutect2, varscan2
- ABCC2 | c.1769G>A p.R590H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751940502, COSV64986658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCF1 | c.564+2T>C p.X188_splice | Splice Site (SNP) | VAF 76/185 reads (41%) | catalogued as COSV100400811; called by muse, mutect2, varscan2
- ABCF1 | c.985G>A p.G329S (on ENST00000326195 / NM_001025091.2; = p.G291S on NM_001090.3) | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs527747770, COSV58229427; called by muse, mutect2, varscan2
- ABCG2 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs753759474, CM1314536, COSV52942694; called by muse, mutect2, varscan2
- ABCG8 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762452685, COSV55391738; called by muse, mutect2, varscan2
- ABI3 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as rs200111501, COSV56800440; called by muse, mutect2
- AC068580.4 | c.91T>C p.S31P | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.479); catalogued as COSV52588537; called by muse, mutect2, varscan2
- AC126283.2 | c.111del p.K37Nfs*65 | Frame Shift Del (DEL) | VAF 40/115 reads (35%) | catalogued as rs1560546604; called by mutect2, varscan2
- ACAN | c.4388C>T p.A1463V | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.843); catalogued as rs369619909; called by muse, mutect2, varscan2
- ACAP3 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs768986239, COSV100686335; called by muse, mutect2, varscan2
- ACMSD | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs368920093, COSV99299022; called by mutect2, varscan2
- ACSM2A | c.1666G>T p.G556W (on ENST00000219054; = p.G477W on NM_001308169.2) | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54584160, COSV54585652; called by muse, mutect2, varscan2
- ACSM4 | c.943A>C p.T315P | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68068033; called by muse, mutect2, varscan2
- ACTN2 | c.2641T>C p.Y881H | Missense Mutation (SNP) | VAF 52/75 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV63971999; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 60/74 reads (81%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM2 | c.1976G>A p.G659D | Missense Mutation (SNP) | VAF 102/271 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55863420; called by muse, mutect2, varscan2
- ADAMTS13 | c.3368G>A p.R1123H | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs782311861, CM1313286, COSV52470461; called by muse, mutect2, varscan2
- ADAMTS14 | c.2318C>T p.A773V | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.135); catalogued as COSV64602852; called by muse, mutect2, varscan2
- ADAMTS18 | c.3158G>A p.R1053Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs534278374, COSV51399098; called by muse, mutect2, varscan2
- ADAMTS8 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 37/107 reads (35%) | catalogued as rs764824360, COSV99960859; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4274-1G>T p.X1425_splice | Splice Site (SNP) | VAF 53/208 reads (25%) | catalogued as COSV54448892, COSV54451841; called by muse, mutect2, varscan2
- ADARB1 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs777063481, COSV62344849; called by muse, mutect2, varscan2
- ADD1 | c.709G>A p.V237I | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs140019569; called by muse, mutect2, varscan2
- ADGRB1 | c.4097G>A p.S1366N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60097910; called by muse, mutect2, varscan2
- ADGRD1 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1296156870, COSV55439564; called by muse, mutect2, varscan2
- ADGRE1 | c.2262C>A p.F754L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV51671667, COSV51676539, COSV51676675; called by muse, mutect2, varscan2
- ADGRE5 | c.1667C>T p.A556V (on ENST00000242786 / NM_078481.4; = p.A463V on NM_001784.5) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as rs1205766842, COSV99660276; called by muse, mutect2, varscan2
- ADGRG7 | c.2098G>A p.V700I | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as COSV56296155; called by muse, mutect2, varscan2
- ADGRL1 | c.1825C>T p.R609* (on ENST00000340736 / NM_001008701.3; = p.R604* on NM_014921.5) | Nonsense Mutation (SNP) | VAF 23/43 reads (53%) | catalogued as COSV61565054; called by muse, mutect2, varscan2
- ADGRL3 | c.2444T>C p.L815P (on ENST00000506720 / NM_001322402.2; = p.L747P on NM_015236.6) | Missense Mutation (SNP) | VAF 81/194 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72230829; called by muse, mutect2, varscan2
- ADGRV1 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV67987164; called by muse, mutect2, varscan2
- ADGRV1 | c.4472C>T p.T1491M | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs138373307, COSV67979898; called by muse, mutect2, varscan2
- ADRB3 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61462126; called by muse, mutect2, varscan2
- AEBP1 | c.2428G>A p.A810T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as COSV56258634; called by muse, mutect2, varscan2
- AGAP1 | c.1855C>T p.R619C (on ENST00000304032 / NM_001037131.3; = p.R566C on NM_014914.5) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs770626614, COSV58328562; called by muse, mutect2, varscan2
- AGAP3 | c.1769C>T p.A590V (on ENST00000622464; = p.A626V on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.067); catalogued as COSV101257132; called by muse, mutect2, varscan2
- AGPAT2 | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100451958; called by muse, mutect2, varscan2
- AKAP13 | c.6032G>A p.R2011H (on ENST00000394518 / NM_007200.5; = p.R2015H on NM_006738.6) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs778424032, COSV63448023, COSV63464936; called by muse, mutect2, varscan2
- AKAP7 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 168/413 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs140783900, COSV53835698; called by muse, mutect2, varscan2
- AKR1B1 | c.374T>C p.L125S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.107); catalogued as COSV53647549; called by muse, mutect2, varscan2
- AL136295.1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs1394432466, COSV55303474; called by muse, mutect2, varscan2
- AL441992.2 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs770205049, COSV56913694; called by muse, mutect2, varscan2
- AL713999.2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 176/295 reads (60%) | catalogued as rs372181365, COSV99825951; called by muse, mutect2, varscan2
- ALAS2 | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 18/21 reads (86%) | catalogued as COSV58191336; called by muse, mutect2, varscan2
- ALDH16A1 | c.1906del p.A636Pfs*12 | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | catalogued as rs1462501220; called by mutect2, pindel, varscan2
- ALG12 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | PolyPhen probably damaging (1); catalogued as rs149109851; called by muse, mutect2
- ALG13 | c.2605G>A p.A869T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as rs1202237862, COSV52640119; called by muse, mutect2, varscan2
- ALOX12 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs776380897, COSV52350402; called by muse, mutect2, varscan2
- AMHR2 | c.800dup p.P268Sfs*30 | Frame Shift Ins (INS) | VAF 12/33 reads (36%) | catalogued as rs748387033; called by mutect2, varscan2
- ANAPC4 | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59544565; called by muse, mutect2, varscan2
- ANK1 | c.2855G>A p.R952H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780841364, COSV55874073; called by muse, mutect2, varscan2
- ANKS1B | c.1733A>G p.K578R | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV61355394, COSV61371101; called by muse, mutect2
- ANO9 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs775078390, COSV60449760; called by muse, mutect2, varscan2
- ANP32A | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as COSV51189624; called by muse, mutect2, varscan2
- AOC3 | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs555331668, COSV53826982; called by muse, mutect2, varscan2
- AP3D1 | c.2664G>T p.K888N | Missense Mutation (SNP) | VAF 108/268 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.296); catalogued as COSV61429160; called by muse, mutect2, varscan2
- APC | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs371453363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.4538G>A p.R1513Q | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780817600, COSV51931789; ClinVar: likely benign; called by muse, mutect2, varscan2
- APOBEC3D | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs749813878, COSV53326966; called by muse, mutect2, varscan2
- ARAP1 | c.1288G>A p.A430T (on ENST00000393609 / NM_001040118.2; = p.A185T on NM_015242.4) | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs770678426, COSV61991716; called by muse, mutect2, varscan2
- ARHGAP25 | c.1846C>T p.R616C (on ENST00000409202 / NM_001007231.3; = p.R608C on NM_014882.3) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.963); catalogued as rs764265797, COSV54903451; called by muse, mutect2, varscan2
- ARHGAP27 | c.2338G>A p.E780K (on ENST00000428638 / NM_001282290.1; = p.E439K on NM_199282.3) | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1356084965, COSV65357900; called by muse, mutect2, varscan2
- ARHGEF10L | c.3679G>A p.A1227T | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs766792968, COSV51434110, COSV99393247; called by muse, mutect2, varscan2
- ARHGEF12 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779478124, COSV63105328; called by muse, mutect2, varscan2
- ARHGEF4 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs1163234445, COSV58123637; called by muse, mutect2, varscan2
- ARID1A | c.671del p.P224Rfs*8 | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | catalogued as rs1462224784; called by mutect2, pindel, varscan2
- ARID1A | c.4160A>G p.E1387G | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV61379388; called by muse, mutect2, varscan2
- ARID5B | c.2800A>G p.S934G | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1195081675, COSV99689540; called by muse, mutect2, varscan2
- ARPP21 | c.1147A>G p.S383G | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV51799722; called by muse, mutect2, varscan2
- ASB1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1031302620, COSV52827966; called by muse, mutect2, varscan2
- ASB13 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs60413325, COSV63091009, COSV99069891; called by muse, mutect2, varscan2
- ASIC4 | c.385A>G p.S129G | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV61732064; called by muse, mutect2, varscan2
- ASMTL | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs371067058, COSV67243924; called by muse, mutect2, varscan2
- ASPM | c.7526T>C p.L2509P | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV54131523; called by muse, mutect2, varscan2
- ATCAY | c.1002C>T p.S334= | Splice Region (SNP) | VAF 10/35 reads (29%) | catalogued as rs767813874, COSV56656481; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATG16L2 | c.1528C>A p.L510I | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.381); catalogued as COSV58361989; called by muse, mutect2, varscan2
- ATP1A4 | c.3082T>C p.Y1028H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1455574125, COSV63624242; called by muse, mutect2, varscan2
- ATP1B4 | c.912+1G>A p.X304_splice (on ENST00000218008 / NM_001142447.3; = p.X300_splice on NM_012069.5) | Splice Site (SNP) | VAF 5/39 reads (13%) | catalogued as rs777822720, COSV54313550; called by mutect2, varscan2
- ATP2A1 | c.545-1G>T p.X182_splice | Splice Site (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100837085; called by muse, mutect2, varscan2
- ATP4A | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV52868670; called by muse, mutect2, varscan2
- ATP5F1C | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.399); catalogued as rs758013111, COSV59621773; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1165G>A p.G389R | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV57749821, COSV57752146; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs761913726, COSV57749833; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1381T>C p.Y461H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59476816; called by muse, mutect2, varscan2
- ATP9A | c.2095G>T p.D699Y | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.82); catalogued as COSV58767676, COSV58769723; called by muse, mutect2, varscan2
- ATRX | c.3683C>A p.P1228H | Missense Mutation (SNP) | VAF 67/85 reads (79%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as COSV64877960; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- AUTS2 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.214); catalogued as rs367855382; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AXL | c.874del p.H292Ifs*5 | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | catalogued as rs778012871; called by mutect2, pindel, varscan2
- BAALC | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs1428437677, COSV52562677; called by muse, mutect2, varscan2
- BAG6 | c.2317C>T p.R773C (on ENST00000676571; = p.R726C on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52990692; called by muse, mutect2, varscan2
- BAZ1B | c.1283T>C p.L428P | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs781852526, COSV59991789; called by muse, mutect2
- BBS2 | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as COSV55326874; called by muse, mutect2, varscan2
- BCHE | c.305C>A p.P102Q | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV52257730; called by muse, mutect2, varscan2
- BCL2 | c.82T>C p.Y28H | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs1555711318, COSV61382395; called by muse, mutect2, varscan2
- BCL7A | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 38/93 reads (41%) | catalogued as COSV55848938; called by muse, mutect2, varscan2
- BDNF | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339220115, COSV59234219; called by muse, mutect2, varscan2
- BMERB1 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1370960780, COSV55512590; called by muse, mutect2
- BMS1 | c.588G>T p.K196N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV65734199; called by muse, mutect2, varscan2
- BORCS6 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.557); catalogued as rs1174520058, COSV66505259; called by muse, mutect2, varscan2
- BPI | c.398G>A p.G133D (on ENST00000262865; = p.G129D on NM_001725.3) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53406135; called by muse, mutect2, varscan2
- BPIFB3 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs202072797, COSV64956812; called by muse, mutect2, varscan2
- BPTF | c.1979G>A p.C660Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV58838801; called by muse, mutect2, varscan2
- BRAF | c.860+2T>C p.X287_splice | Splice Site (SNP) | VAF 45/119 reads (38%) | catalogued as COSV56212237; called by muse, mutect2, varscan2
- BRCA1 | c.3298G>A p.G1100R | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1555587999, COSV58791833; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD1 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53458167; called by muse, mutect2, varscan2
- BRD7 | c.757A>G p.T253A | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101164883; called by muse, mutect2, varscan2
- BRWD1 | c.4054G>A p.D1352N | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs370655540; called by muse, mutect2, varscan2
- BTBD16 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs755133680, COSV53263829; called by muse, mutect2, varscan2
- BTN2A2 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.86); catalogued as rs370867259; called by muse, mutect2, varscan2
- C10orf88 | c.401dup p.N134Kfs*12 | Frame Shift Ins (INS) | VAF 76/229 reads (33%) | catalogued as rs751388819; called by mutect2, varscan2
- C5AR1 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.012); catalogued as rs770659810, COSV61892721, COSV61892949; called by muse, mutect2, varscan2
- C6orf89 | c.292C>T p.R98C (on ENST00000373685; = p.R105C on NM_152734.4) | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs571648523, COSV62102100; called by muse, mutect2, varscan2
- C8orf34 | c.1292T>G p.L431R | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.221); catalogued as COSV100297742, COSV57404667; called by muse, mutect2, varscan2
- CA2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs555992309, COSV53407174; called by muse, mutect2, varscan2
- CACNA1C | c.5158del p.Q1720Rfs*132 (on ENST00000399634 / NM_001167625.1; = p.Q1720Rfs*120 on NM_000719.7) | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | catalogued as COSV59734542; called by mutect2, pindel, varscan2
- CACNA1E | c.6152G>A p.R2051H (on ENST00000367573 / NM_001205293.3; = p.R2008H on NM_000721.4) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV62399825; called by muse, mutect2
- CACNA1E | c.6553C>T p.P2185S (on ENST00000367573 / NM_001205293.3; = p.P2142S on NM_000721.4) | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs548645440, COSV62399830; called by muse, mutect2, varscan2
- CACNA1G | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1335556091, COSV61720237; called by muse, mutect2, varscan2
- CACNB2 | c.1124C>T p.A375V (on ENST00000324631 / NM_201596.3; = p.A320V on NM_000724.4) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs578106427, COSV56622691; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CADM4 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55929099; called by muse, mutect2, varscan2
- CADPS | c.2573A>C p.K858T | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV51883847; called by muse, mutect2, varscan2
- CADPS | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs898296147, COSV51871719; called by muse, mutect2
- CALML3 | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.717); catalogued as rs892654657, COSV59449456; called by muse, mutect2, varscan2
- CAMKK1 | c.379C>A p.Q127K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50118704; called by muse, mutect2, varscan2
- CAMKK2 | c.475T>G p.C159G | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1407871256, COSV61215257; called by muse, mutect2, varscan2
- CAPN5 | c.1519C>T p.R507C (on ENST00000456580; = p.R467C on NM_004055.5) | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1064797159, COSV53688695; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARD10 | c.1578del p.S527Vfs*31 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs35832225; called by mutect2, pindel, varscan2
- CARD11 | c.1780G>A p.G594S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs567929694, COSV62754522; called by muse, mutect2, varscan2
- CARD14 | c.2929G>A p.D977N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777211579, COSV58339458; called by muse, mutect2, varscan2
- CASKIN2 | c.3519-1G>T p.X1173_splice | Splice Site (SNP) | VAF 7/54 reads (13%) | catalogued as COSV58596589; called by muse, mutect2, varscan2
- CASP14 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs200139686, COSV55665640; called by muse, mutect2, varscan2
- CASZ1 | c.2985G>T p.K995N | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV59736707; called by muse, mutect2, varscan2
- CCDC110 | c.1774del p.T592Hfs*5 | Frame Shift Del (DEL) | VAF 35/284 reads (12%) | catalogued as rs368765497; called by mutect2, varscan2
- CCDC149 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 9/55 reads (16%) | catalogued as rs779854245, COSV60879603; called by muse, mutect2, varscan2
- CCDC50 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 104/284 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776014358, COSV66667353; called by muse, mutect2, varscan2
- CCDC7 | c.3497C>T p.T1166M | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs181757977, COSV56543821; called by muse, mutect2, varscan2
- CCDC88A | c.2335del p.I779Sfs*4 | Frame Shift Del (DEL) | VAF 76/208 reads (37%) | catalogued as COSV55059558; called by mutect2, pindel, varscan2
- CCDC96 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs776708081, COSV59508776; called by muse, mutect2, varscan2
- CCKBR | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.318); catalogued as rs746523028, COSV58102335, COSV58105140; called by muse, mutect2, varscan2
- CD300C | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.13); catalogued as COSV58170632; called by muse, mutect2, varscan2
- CD8A | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs200418942, COSV52157871; called by muse, mutect2, varscan2
- CDC14A | c.375dup p.Y126Lfs*35 | Frame Shift Ins (INS) | VAF 36/124 reads (29%) | catalogued as rs773911500; called by mutect2, varscan2
- CDC42EP4 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs769821399, COSV59963113; called by muse, mutect2, varscan2
- CDC45 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs541752640, COSV54246177; called by muse, mutect2
- CDH6 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs777622672, COSV54064764; called by muse, mutect2, varscan2
- CDHR2 | c.2171C>T p.T724M | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs113163991; called by mutect2, varscan2
- CDK2AP2 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1482336115, COSV56874396; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4913C>A p.A1638D | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as COSV62574951; called by muse, mutect2, varscan2
- CDKL4 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 40/96 reads (42%) | catalogued as rs771548328, COSV101115322, COSV66509906; called by muse, mutect2, varscan2
- CDON | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV54998856; called by muse, mutect2, varscan2
- CDYL2 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs1056402563, COSV73647707; called by muse, mutect2, varscan2
- CEBPG | c.337A>G p.K113E | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1180122040, COSV52287556; called by muse, mutect2, varscan2
- CEL | c.709C>T p.R237W (on ENST00000673714; = p.R234W on NM_001807.6) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs746040301, COSV60827944; called by muse, mutect2, varscan2
- CELF4 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV100611549; called by muse, mutect2
- CELF4 | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.94); PolyPhen benign (0.116); catalogued as COSV100611550; called by muse, mutect2, varscan2
- CELSR3 | c.3763G>A p.V1255M | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV50880907; called by muse, mutect2, varscan2
- CELSR3 | c.2657A>G p.D886G | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50881154; called by muse, mutect2, varscan2
- CEP170 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 55/367 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.398); catalogued as COSV100316981; called by muse, mutect2, varscan2
- CEP170B | c.1280C>T p.P427L (on ENST00000453495; = p.P356L on NM_015005.3) | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs554565193, COSV69024969; called by muse, mutect2, varscan2
- CEP170B | c.3499C>T p.R1167C (on ENST00000453495; = p.R1096C on NM_015005.3) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866933875, COSV69024975; called by muse, mutect2, varscan2
- CEP63 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs181828481, COSV100133111, COSV59674801; called by muse, mutect2, varscan2
- CEP95 | c.1064T>C p.F355S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV73609326; called by muse, mutect2, varscan2
- CETN1 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV59121006; called by muse, mutect2, varscan2
- CFAP61 | c.3047C>A p.P1016Q | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55632731; called by muse, mutect2, varscan2
- CGAS | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as rs373045600, COSV64807932; called by muse, mutect2, varscan2
- CGN | c.2755C>T p.R919W | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757845776, COSV54970634; called by muse, mutect2, varscan2
- CHD1 | c.4872A>C p.K1624N | Missense Mutation (SNP) | VAF 83/179 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.95); catalogued as COSV52341160; called by muse, mutect2, varscan2
- CHD1 | c.2395C>T p.R799C | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99399383; called by muse, mutect2, varscan2
- CHD2 | c.3751C>T p.R1251C | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV67710331; called by muse, mutect2, varscan2
- CHPF | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.268); catalogued as rs746645222, COSV60535077; called by muse, mutect2, varscan2
- CHRNA10 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.34); catalogued as rs2231543, COSV51705109; called by muse, mutect2, varscan2
- CHST6 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.297); catalogued as COSV60000636; called by muse, mutect2, varscan2
- CIITA | c.1962dup p.G655Rfs*94 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | catalogued as rs778982759; called by mutect2, varscan2
- CLCN4 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV66465228; called by muse, mutect2, varscan2
- CLSTN3 | c.2858dup p.H954Tfs*163 | Frame Shift Ins (INS) | VAF 27/61 reads (44%) | catalogued as rs758841384; called by mutect2, varscan2
- CMKLR1 | c.1068G>A p.M356I (on ENST00000312143 / NM_001142344.2; = p.M354I on NM_004072.3) | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.147); catalogued as COSV56438908; called by muse, mutect2, varscan2
- CNNM2 | c.1429G>A p.G477S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV63996015; called by muse, mutect2
- CNNM3 | c.1925C>T p.T642M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs770397651, COSV59709341; called by muse, mutect2, varscan2
- CNOT1 | c.4613G>A p.R1538H | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1392510408, COSV55317817; called by muse, mutect2, varscan2
- CNOT3 | c.1189G>A p.G397R | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0.046); catalogued as rs765712541, COSV55364138; called by muse, mutect2, varscan2
- CNOT7 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs375278542; called by muse, mutect2, varscan2
- CNTN6 | c.2715A>C p.Q905H | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100610590; called by muse, mutect2, varscan2
- COL11A1 | c.3679A>G p.R1227G | Missense Mutation (SNP) | VAF 137/400 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs868033385, COSV62185782; called by muse, mutect2, varscan2
- COL15A1 | c.2546C>T p.P849L | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66645956; called by muse, mutect2, varscan2
- COL16A1 | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1192478645, COSV54707657; called by muse, mutect2, varscan2
- COL4A4 | c.5022G>T p.Q1674H | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV61633038; called by muse, mutect2, varscan2
- COL5A2 | c.2761G>A p.G921S | Missense Mutation (SNP) | VAF 29/360 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1051200074, COSV66410586; called by muse, mutect2
- COL6A1 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs181256566, COSV62611743; called by muse, mutect2, varscan2
- COL6A2 | c.1120del p.X374_splice | Splice Site (DEL) | VAF 27/94 reads (29%) | catalogued as COSV100154027; called by mutect2, pindel, varscan2
- COPS5 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as COSV63474508; called by muse, mutect2, varscan2
- COX10 | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV55405626; called by muse, mutect2, varscan2
- COX8A | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs550927126, COSV58478826; called by muse, mutect2, varscan2
- CPA2 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs145958174; called by muse, mutect2, varscan2
- CPA5 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs200717171; called by muse, mutect2, varscan2
- CPE | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.151); catalogued as COSV68580794; called by muse, mutect2, varscan2
- CPEB1 | c.440G>A p.R147H (on ENST00000617958; = p.R87H on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV55619431, COSV99917926; called by muse, mutect2, varscan2
- CPED1 | c.2711T>C p.F904S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100120583; called by muse, mutect2, varscan2
- CPSF2 | c.1654del p.I552Sfs*5 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | catalogued as rs758712860; called by pindel, varscan2
- CPSF3 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 93/231 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs757160812, COSV53009954; called by muse, mutect2, varscan2
- CRADD | c.391T>C p.W131R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373657793; called by muse, mutect2, varscan2
- CROCC | c.2855G>A p.R952Q | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs768170307, COSV65012615; called by muse, mutect2, varscan2
- CROT | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 52/164 reads (32%) | catalogued as rs377633206; called by muse, mutect2, varscan2
- CRP | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 72/120 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.797); catalogued as COSV54813780; called by muse, mutect2, varscan2
- CRYGB | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs377246959; called by muse, mutect2, varscan2
- CSDC2 | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761802158, COSV53448023; called by muse, mutect2, varscan2
- CSDE1 | c.1535G>A p.R512H (on ENST00000358528 / NM_001007553.3; = p.R481H on NM_007158.6) | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs765999933, COSV54748990; called by muse, mutect2, varscan2
- CSF3R | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 77/228 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV58967833; called by muse, mutect2, varscan2
- CSMD1 | c.3416C>T p.A1139V (on ENST00000520002; = p.A1138V on NM_033225.6) | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.996); catalogued as COSV59318416, COSV59325476; called by muse, mutect2, varscan2
- CSMD2 | c.4285G>A p.E1429K | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs532612359, COSV53920454; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs766438669; called by pindel, varscan2
- CTBP1 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52074552; called by muse, mutect2, varscan2
- CTDSP2 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs764230836, COSV66079896; called by muse, mutect2, varscan2
- CTNNA1 | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs139655691; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA3 | c.2568dup p.P857Tfs*4 | Frame Shift Ins (INS) | VAF 44/147 reads (30%) | catalogued as rs759618368; called by mutect2, varscan2
- CTRL | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs200180034, COSV52123753; called by muse, mutect2, varscan2
- CTSF | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs779164010, COSV59748100; called by muse, mutect2, varscan2
- CUL1 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 29/87 reads (33%) | catalogued as COSV57391531; called by muse, mutect2, varscan2
- CUX1 | c.1282G>C p.A428P | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs782489323, COSV52895909; called by muse, mutect2, varscan2
- CUX1 | c.1591C>A p.L531M (on ENST00000437600 / NM_181500.4; = p.L533M on NM_001913.5) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV52933975; called by muse, mutect2, varscan2
- CWC22 | c.2695C>T p.R899* | Nonsense Mutation (SNP) | VAF 52/158 reads (33%) | catalogued as rs752315626, COSV55427210; called by muse, mutect2, varscan2
- CXCR5 | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | catalogued as rs373329724; called by muse, mutect2, varscan2
- CYFIP1 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.179); catalogued as rs746030413; called by muse, mutect2, varscan2
- CYP2E1 | c.1015C>A p.P339T | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53312455, COSV53313774; called by muse, mutect2, varscan2
- DCAF11 | c.1215G>A p.W405* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | catalogued as COSV100386558; called by muse, mutect2, varscan2
- DCAF12L1 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.05); PolyPhen benign (0.413); catalogued as rs776979926, COSV64421181; called by muse, mutect2, varscan2
- DCAF12L2 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs769240535, COSV63580305, COSV63583513; called by muse, mutect2, varscan2
- DCHS1 | c.3358C>A p.P1120T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100201967; called by muse, mutect2
- DCLK2 | c.2288G>A p.R763H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.375); catalogued as rs1421294372, COSV56205522; called by muse, mutect2
- DCPS | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs768453817, COSV55011171; called by muse, mutect2, varscan2
- DCSTAMP | c.317T>C p.V106A | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV52578132; called by muse, mutect2, varscan2
- DDHD2 | c.746T>G p.L249R | Missense Mutation (SNP) | VAF 90/202 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV68158041; called by muse, mutect2, varscan2
- DDX54 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs139285972; called by muse, mutect2, varscan2
- DEFB113 | c.73del p.T25Qfs*? | Frame Shift Del (DEL) | VAF 29/109 reads (27%) | catalogued as rs758917875, COSV104398000; called by mutect2, pindel, varscan2
- DENND1A | c.1601G>T p.R534M | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV65351360; called by muse, mutect2, varscan2
- DENND3 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs763676755, COSV52801775; called by muse, mutect2, varscan2
- DENR | c.323del p.K108Rfs*10 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs1566061026; called by mutect2, pindel, varscan2
- DHX16 | c.2108G>A p.R703H | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs768833519, COSV53312776; called by muse, mutect2, varscan2
- DHX57 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs138902985; called by muse, mutect2, varscan2
- DIAPH1 | c.2108dup p.P704Tfs*71 | Frame Shift Ins (INS) | VAF 11/32 reads (34%) | catalogued as rs771360300; called by mutect2, varscan2
- DIDO1 | c.2011C>T p.R671W | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56616894, COSV56628444; called by muse, mutect2, varscan2
- DIS3L2 | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56056229, COSV99806684; called by muse, mutect2, varscan2
- DKK2 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 82/189 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53398608; called by muse, mutect2, varscan2
- DLGAP1 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV59809839; called by muse, mutect2, varscan2
- DMXL1 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 72/140 reads (51%) | catalogued as COSV60713583; called by muse, mutect2, varscan2
- DMXL1 | c.4982dup p.N1661Kfs*13 | Frame Shift Ins (INS) | VAF 53/129 reads (41%) | catalogued as rs1029723468; called by mutect2, varscan2
- DNAH17 | c.8891C>T p.A2964V | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760238543, COSV67756311; called by muse, mutect2, varscan2
- DNAH2 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.31); catalogued as rs768754911, COSV50015282; called by muse, mutect2, varscan2
- DNAH5 | c.12596G>A p.R4199H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375694023, COSV54231165; called by muse, mutect2, varscan2
- DNAH7 | c.3001T>C p.S1001P | Missense Mutation (SNP) | VAF 31/279 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.485); catalogued as COSV100414967; called by muse, mutect2, varscan2
- DNAH9 | c.12592A>G p.T4198A | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.58); catalogued as COSV52345424; called by muse, mutect2, varscan2
- DOCK5 | c.2152A>G p.T718A | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as rs779224941, COSV52403716; called by muse, mutect2, varscan2
- DOHH | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs765301122, COSV51745124; called by muse, mutect2, varscan2
- DPF2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs899257334, COSV52889724; called by muse, mutect2, varscan2
- DPH5 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 78/197 reads (40%) | catalogued as rs376566442; called by muse, mutect2, varscan2
- DPP10 | c.1849C>T p.R617* | Nonsense Mutation (SNP) | VAF 43/121 reads (36%) | catalogued as COSV59680985, COSV59692600; called by muse, mutect2, varscan2
- DSCAML1 | c.3358G>A p.A1120T (on ENST00000321322; = p.A1060T on NM_020693.4) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs372736535, COSV58392742; called by muse, mutect2, varscan2
- DSP | c.8020G>A p.A2674T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397516961, COSV60939096; ClinVar: uncertain significance; called by mutect2, varscan2
- DSP | c.8276G>A p.R2759H | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs936541705, COSV60939749; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTNA | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.893); catalogued as rs760288717, COSV52006693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTNA | c.1970A>C p.E657A | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as COSV52007318; called by muse, mutect2
- DXO | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs780217920, COSV61713118; called by muse, mutect2, varscan2
- DYNC1H1 | c.7033G>C p.V2345L | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64137927; called by muse, mutect2, varscan2
- DYNC2H1 | c.11417G>A p.R3806H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1515016, COSV62096285; called by muse, mutect2, varscan2
- DYRK1B | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as rs761527610, COSV100546557; called by muse, mutect2
- E4F1 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV57038138, COSV57039428; called by muse, mutect2, varscan2
- EDA2R | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as COSV53631756; called by muse, mutect2, varscan2
- EDEM3 | c.1408C>A p.L470I | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100545213; called by muse, mutect2, varscan2
- EEF2K | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375672467; called by muse, mutect2, varscan2
- EFCAB1 | c.479A>G p.D160G | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50617923; called by muse, mutect2, varscan2
- EGR1 | c.1000del p.H334Tfs*198 | Frame Shift Del (DEL) | VAF 44/123 reads (36%) | catalogued as rs746692720; called by mutect2, pindel, varscan2
- EGR1 | c.1210A>G p.K404E | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV53519933; called by muse, mutect2, varscan2
- EGR2 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV54346517; called by muse, mutect2, varscan2
- EHBP1 | c.2585G>A p.R862H | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs748923200, COSV50421992; called by muse, mutect2, varscan2
- EHMT2 | c.3394C>T p.R1132* | Nonsense Mutation (SNP) | VAF 31/80 reads (39%) | catalogued as COSV57667592; called by muse, mutect2, varscan2
- EHMT2 | c.2060C>T p.T687M | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs956822938, COSV64996344; called by muse, mutect2, varscan2
- EIF3A | c.3823C>A p.R1275S | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.1); catalogued as COSV64960524, COSV64961733; called by muse, mutect2, varscan2
- EIF4G1 | c.2441C>T p.A814V (on ENST00000346169 / NM_198241.3; = p.A619V on NM_004953.5) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV59991529; called by muse, mutect2, varscan2
- EIF4G2 | c.2361dup p.S788Qfs*3 | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | catalogued as rs781635731; called by mutect2, varscan2
- ELAVL3 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 75/215 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.212); catalogued as rs144705960; called by muse, mutect2, varscan2
- ELF2 | c.1702G>A p.V568I (on ENST00000379550 / NM_001331036.2; = p.V508I on NM_006874.4) | Missense Mutation (SNP) | VAF 118/273 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as COSV55493692; called by muse, mutect2, varscan2
- ELFN2 | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV68744093; called by muse, mutect2, varscan2
- ELOF1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 128/299 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs775976345, COSV52947843; called by muse, mutect2, varscan2
- ENPEP | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.228); catalogued as rs146706022; called by muse, mutect2, varscan2
- ENPP2 | c.1180C>T p.R394* (on ENST00000075322 / NM_001040092.3; = p.R446* on NM_006209.5) | Nonsense Mutation (SNP) | VAF 42/103 reads (41%) | catalogued as COSV50010426; called by muse, mutect2, varscan2
- ENTPD2 | c.1414G>A p.A472T (on ENST00000355097 / NM_203468.3; = p.A449T on NM_001246.4) | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs753972936, COSV57075626; called by muse, mutect2, varscan2
- EOGT | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as rs779799662, COSV55151647; called by muse, mutect2, varscan2
- EPHA1 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | catalogued as rs141528182; called by muse, mutect2, varscan2
- EPHA3 | c.1516G>A p.V506I | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV60709807; called by muse, mutect2, varscan2
- EPHA6 | c.2078G>A p.R693H (on ENST00000389672 / NM_001080448.3; = p.R85H on NM_173655.4) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs755277174, COSV67575941; called by muse, mutect2, varscan2
- EPHB3 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.976); catalogued as rs141064214; called by muse, mutect2, varscan2
- EPHB6 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs1005868917, COSV67418045; called by muse, mutect2, varscan2
- EPN1 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs1169691224, COSV50038632; called by muse, mutect2, varscan2
- ERCC6L2 | c.3671G>A p.R1224H | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs369846292; called by muse, mutect2, varscan2
- ESR1 | c.650A>G p.N217S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV52792764; called by muse, mutect2, varscan2
- ESR2 | c.1504G>A p.G502R | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as rs766524153, COSV50832692; called by muse, mutect2, varscan2
- ESRRA | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767507136, COSV50005346; called by muse, mutect2, varscan2
- ESYT2 | c.2311C>T p.Q771* (on ENST00000613624; = p.Q695* on NM_020728.3) | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV51752111; called by muse, mutect2, varscan2
- ESYT3 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.954); catalogued as rs376528570, COSV56680670; called by mutect2, varscan2
- ETV6 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs376242225; called by muse, mutect2, varscan2
- EVI5 | c.648del p.F216Lfs*15 | Frame Shift Del (DEL) | VAF 13/122 reads (11%) | catalogued as rs1453325274; called by mutect2, pindel, varscan2
- EVPL | c.3907C>T p.R1303C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs779308644, COSV56910227; called by muse, mutect2, varscan2
- EYA2 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.338); catalogued as COSV100426738; called by muse, mutect2, varscan2
- FAM162B | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as rs1468062485, COSV63920285; called by muse, mutect2, varscan2
- FAM210A | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV59184484; called by muse, mutect2, varscan2
- FAM220A | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs551319790, COSV57626128; called by muse, mutect2, varscan2
- FAM71A | c.1375T>G p.S459A | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV54236038; called by muse, mutect2, varscan2
- FAM71F2 | c.79_81del p.L27del | In Frame Del (DEL) | VAF 22/60 reads (37%) | catalogued as rs777765887; called by pindel, varscan2
- FARSA | c.437del p.G146Dfs*14 | Frame Shift Del (DEL) | VAF 26/83 reads (31%) | catalogued as rs746493788; called by mutect2, pindel, varscan2
- FAT3 | c.4091A>C p.E1364A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); catalogued as COSV53122338; called by muse, mutect2, varscan2
- FBP2 | c.503A>G p.Y168C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV64694837; called by muse, mutect2, varscan2
- FBXL5 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.374); catalogued as rs764719880, COSV58011835; called by muse, mutect2, varscan2
- FBXO31 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV61149347; called by muse, mutect2, varscan2
- FBXO34 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1317415064, COSV58254894; called by muse, mutect2, varscan2
- FCER2 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as rs145289159; called by muse, mutect2, varscan2
- FCGR2A | c.221A>C p.Q74P (on ENST00000271450 / NM_001136219.3; = p.Q73P on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs773080023, COSV54839146; called by muse, mutect2, varscan2
- FCRL3 | c.1976A>C p.N659T | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as rs1452020930, COSV100943154; called by muse, mutect2
- FERMT3 | c.1121G>A p.R374H (on ENST00000279227 / NM_178443.3; = p.R370H on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs1297918425, COSV54180620; called by muse, mutect2, varscan2
- FFAR2 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as rs771781550, COSV55831802; called by muse, mutect2, varscan2
- FGD2 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs763769959, COSV51462237; called by mutect2, varscan2
- FGF12 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs1305557640, COSV53169187; called by muse, mutect2, varscan2
- FGF5 | c.441del p.G148Efs*45 | Frame Shift Del (DEL) | VAF 54/228 reads (24%) | catalogued as rs35667286; called by mutect2, varscan2
- FHOD1 | c.974C>T p.T325M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs1162115126, COSV50759762; called by muse, mutect2, varscan2
- FN3K | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1318653526, COSV56183273; called by muse, mutect2, varscan2
- FNTB | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs764500262, COSV55762044; called by muse, mutect2, varscan2
- FOXP4 | c.1319G>A p.R440Q (on ENST00000307972 / NM_001012426.1; = p.R427Q on NM_138457.3) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs576059149, COSV57220668; called by muse, mutect2, varscan2
- FOXS1 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770771838, COSV99639703; called by muse, mutect2, varscan2
- FRMPD1 | c.4535G>A p.R1512H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs377415527, COSV66700691; called by muse, mutect2, varscan2
- FSCN2 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs761626389, COSV58367956; called by mutect2, varscan2
- FUBP1 | c.193del p.R65Dfs*3 | Frame Shift Del (DEL) | VAF 95/314 reads (30%) | catalogued as rs759271820; called by pindel, varscan2
- FUT10 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59452109; called by muse, mutect2, varscan2
- GABBR1 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV100589669; called by muse, mutect2, varscan2
- GABRA5 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59480831; called by muse, mutect2, varscan2
- GAPDHS | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 23/82 reads (28%) | catalogued as COSV55882892; called by muse, mutect2, varscan2
- GATA5 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as rs1261156758, COSV53346339; called by muse, mutect2, varscan2
- GCC2 | c.3054_3060+21del p.X1018_splice | Splice Site (DEL) | VAF 39/170 reads (23%) | catalogued as COSV59177027; called by mutect2, pindel, varscan2
- GDF6 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1331641099, COSV54625072; called by muse, mutect2, varscan2
- GFOD1 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64954285; called by muse, mutect2, varscan2
- GFRA1 | c.792dup p.T265Yfs*20 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as rs753876091; called by mutect2, varscan2
- GIT2 | c.1597C>T p.R533C (on ENST00000355312 / NM_057169.5; = p.R485C on NM_014776.5) | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.276); catalogued as rs772698569, COSV58081461; called by muse, mutect2, varscan2
- GLCE | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.151); catalogued as rs756061835, COSV55946358; called by muse, mutect2, varscan2
- GLI3 | c.3392C>T p.A1131V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs750890276, COSV67889541; called by muse, mutect2, varscan2
- GMEB1 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.116); catalogued as COSV53794821; called by muse, mutect2, varscan2
- GNA15 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs774052972, COSV53585996; called by muse, mutect2, varscan2
- GNAS | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as rs777234998, COSV58348517; called by muse, mutect2, varscan2
- GNB1 | c.688A>T p.N230Y | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV66100760; called by muse, mutect2, varscan2
- GNL2 | c.569G>T p.R190I | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV100894985; called by muse, mutect2, varscan2
- GOLGA3 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV52633642; called by muse, mutect2, varscan2
- GP6 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV59978000; called by muse, mutect2, varscan2
- GPBAR1 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs769777368, COSV50307875; called by muse, mutect2, varscan2
- GPR1 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs569840690, COSV67976454; called by muse, mutect2, varscan2
- GPR12 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs753635977, COSV67344437; called by muse, mutect2, varscan2
- GPR132 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs61737889; called by muse, mutect2, varscan2
- GPR173 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT tolerated (0.22); PolyPhen benign (0.376); catalogued as rs781986623, COSV60233793; called by muse, mutect2, varscan2
- GPRC5C | c.892G>A p.V298I (on ENST00000652232; = p.V253I on NM_018653.4) | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775061799, COSV61237358; called by muse, mutect2, varscan2
- GRAMD1B | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768451724, COSV59205786; called by muse, mutect2, varscan2
- GRAMD4 | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100730441; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK3 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs368542145; called by muse, mutect2, varscan2
- GRIN2A | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as rs763500409, COSV58053815; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN2B | c.2812C>T p.R938C | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1477799075, COSV74206269; called by muse, mutect2, varscan2
- GRIP2 | c.3358C>T p.P1120S (on ENST00000619221; = p.P1023S on NM_001080423.4) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1293278529; called by muse, mutect2
- GRIPAP1 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 53/63 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64552337; called by muse, mutect2, varscan2
- GRK3 | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60796835; called by muse, mutect2, varscan2
- GRM8 | c.1180T>C p.S394P | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV58832909; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as rs754199513; called by mutect2, varscan2
- GTPBP8 | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs754004325, COSV55606642; called by muse, mutect2, varscan2
- GUSB | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs1347468886, COSV100512594; called by muse, mutect2
- GYS1 | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777768883, COSV54403343, COSV54404812; called by muse, mutect2, varscan2
- HABP2 | c.1189A>C p.K397Q | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.863); catalogued as COSV63636980; called by muse, mutect2, varscan2
- HADH | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs746680125, COSV58848416; called by muse, mutect2, varscan2
- HAO1 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs780735238, COSV66491844, COSV66492313; called by muse, mutect2, varscan2
- HDAC10 | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.426); catalogued as rs202169873, COSV50549937; called by muse, mutect2, varscan2
- HDLBP | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs777752687, COSV60496982; called by muse, varscan2
- HDLBP | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 40/329 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV60497000; called by muse, varscan2
- HDLBP | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 29/66 reads (44%) | catalogued as COSV60497023; called by muse, mutect2, varscan2
- HECTD4 | c.13100del p.P4367Qfs*21 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | catalogued as rs746492036; called by mutect2, pindel, varscan2
- HEYL | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 28/69 reads (41%) | catalogued as rs769070110, COSV65721702; called by muse, mutect2, varscan2
- HLA-A | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); catalogued as rs1254449463, COSV65141400; called by muse, mutect2
- HM13 | c.855_857del p.K285del | In Frame Del (DEL) | VAF 20/93 reads (22%) | catalogued as rs755662149; called by pindel, varscan2
- HMG20A | c.769G>A p.V257M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs750449982, COSV60312863; called by muse, mutect2, varscan2
- HNF4A | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.155); catalogued as rs757897768, COSV57381036; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNRNPF | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as rs866991837, COSV100563046; called by muse, mutect2, varscan2
- HOOK3 | c.236T>A p.I79N | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1395494478, COSV56883424; called by muse, mutect2, varscan2
- HOXD9 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as COSV50892235; called by muse, mutect2, varscan2
- HSP90AA1 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1463905518, COSV53489134; called by muse, mutect2, varscan2
- HSPA2 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV55970014; called by muse, mutect2, varscan2
- HSPB8 | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56136923; called by muse, mutect2, varscan2
- HSPBP1 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs983824586, COSV55333325; called by muse, mutect2
- HTR1B | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV64051556; called by muse, mutect2, varscan2
- HUWE1 | c.9398G>A p.R3133H | Missense Mutation (SNP) | VAF 41/49 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs782521336, COSV53344467; called by muse, mutect2, varscan2
- HUWE1 | c.7705C>T p.R2569C | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53348662; called by muse, mutect2, varscan2
- ICAM5 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV55746245; called by muse, mutect2, varscan2
- IFIT1B | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs149656549; called by muse, mutect2, varscan2
- IFT122 | c.3211G>T p.G1071C (on ENST00000348417 / NM_052989.3; = p.G1012C on NM_018262.4) | Missense Mutation (SNP) | VAF 53/288 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99959201; called by muse, mutect2, varscan2
- IGFBP2 | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as rs1196737002, COSV52080455; called by muse, mutect2, varscan2
- IGSF9B | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs1343851795, COSV58064091; called by muse, mutect2, varscan2
- IKBKE | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as rs781938435, COSV65625789; called by muse, mutect2, varscan2
- IKZF3 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768846820, COSV53103039; called by muse, mutect2, varscan2
- IL21R | c.718C>T p.L240F | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV61970875; called by muse, mutect2, varscan2
- ILDR2 | c.287G>A p.S96N | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV54831770; called by muse, mutect2, varscan2
- ILF3 | c.2005G>A p.G669S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as rs1358772687, COSV51558645; called by muse, mutect2, varscan2
- ILK | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs759330457, COSV54991578; called by muse, mutect2, varscan2
- INCA1 | c.377G>A p.R126H (on ENST00000574617 / NM_001167986.1; = p.R111H on NM_213726.2) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139552288; called by muse, mutect2, varscan2
- INPP5F | c.631dup p.W211Lfs*3 | Frame Shift Ins (INS) | VAF 50/142 reads (35%) | catalogued as rs768918635; called by mutect2, varscan2
- INVS | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs984016152, COSV52443366; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IRS1 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1044702955, COSV59337195; called by muse, mutect2, varscan2
- ITGA2B | c.1195C>T p.R399W | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV52233007; called by muse, mutect2, varscan2
- ITGA4 | c.1836del p.M612Ifs*5 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as COSV51998079, COSV52000901; called by mutect2, pindel, varscan2
- ITIH1 | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367809051; called by muse, mutect2, varscan2
- ITSN1 | c.2917A>G p.I973V | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1448509034, COSV66083019; called by muse, mutect2, varscan2
- JADE2 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 27/54 reads (50%) | catalogued as COSV50913585; called by muse, mutect2, varscan2
- JAKMIP3 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as rs1273401007, COSV100059955, COSV53819847; called by muse, mutect2, varscan2
- JMJD1C | c.6075del p.E2026Kfs*45 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs1226801045; called by mutect2, varscan2
- KANSL3 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62615983; called by muse, mutect2, varscan2
- KAT2A | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV56791279; called by muse, mutect2, varscan2
- KCNA2 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 29/73 reads (40%) | catalogued as COSV60369277; called by muse, mutect2, varscan2
- KCNAB1 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs370498904, COSV101051438; called by muse, mutect2, varscan2
- KCNAB3 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs767486615, COSV58140626; called by muse, mutect2, varscan2
- KCNG2 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs747734392, COSV60268344; called by muse, mutect2, varscan2
- KCNH2 | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs765717858, COSV51177490, COSV51217143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNIP1 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.023); catalogued as rs1222690098, COSV66177259; called by muse, mutect2, varscan2
- KCNJ11 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV56851811; called by muse, mutect2, varscan2
- KCNJ4 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV57857435; called by muse, mutect2, varscan2
- KCNK1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs554387590, COSV64035351; called by muse, mutect2, varscan2
- KCNN1 | c.611A>G p.H204R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.216); catalogued as COSV55839449; called by muse, mutect2, varscan2
- KCNQ5 | c.1258A>C p.S420R | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV59662086, COSV59665050; called by muse, mutect2
- KDM1A | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs759735931, COSV56500639; called by muse, mutect2, varscan2
- KDM4C | c.2170C>T p.R724W | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs776351428, COSV67187037; called by muse, mutect2, varscan2
- KDM6B | c.2921G>A p.R974Q | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.625); catalogued as rs759948935, COSV54682547; called by muse, mutect2, varscan2
- KIAA0319 | c.2142A>T p.E714D | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV65499239; called by muse, mutect2, varscan2
- KIAA1109 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs778767163, COSV52667519; called by muse, mutect2, varscan2
- KIAA1109 | c.5247T>G p.S1749R | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV99158855; called by muse, mutect2
- KIAA1522 | c.862del p.Q288Rfs*8 (on ENST00000373480 / NM_001198972.2; = p.Q347Rfs*8 on NM_020888.3) | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | catalogued as COSV53867890; called by mutect2, pindel, varscan2
- KIF19 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1274173691, COSV63429646; called by muse, mutect2, varscan2
- KIF1A | c.2181G>T p.W727C | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57486746; called by muse, mutect2, varscan2
- KIF26B | c.2446del p.E816Rfs*15 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as COSV63635972; called by mutect2, pindel, varscan2
- KIF26B | c.2536G>A p.A846T | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs200467850; called by muse, mutect2, varscan2
- KIF9 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs1302353551, COSV55521658; called by muse, mutect2, varscan2
- KIFC1 | c.22del p.L8Yfs*4 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs763606695, COSV65737886; called by mutect2, pindel
- KLF11 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753566657, COSV59940712; called by muse, mutect2, varscan2
- KLHL1 | c.2014A>C p.R672= | Splice Region (SNP) | VAF 25/58 reads (43%) | catalogued as COSV64774087; called by muse, mutect2, varscan2
- KMT2D | c.9430G>A p.A3144T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.017); catalogued as rs752428122, COSV56443019; called by muse, mutect2, varscan2
- KPNB1 | c.2551C>T p.R851W | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs761508578, COSV51597541; called by muse, mutect2, varscan2
- KRR1 | c.1142del p.K381Sfs*8 | Frame Shift Del (DEL) | VAF 46/89 reads (52%) | catalogued as rs761148574; called by mutect2, varscan2
- KRT16 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs530326477, COSV56967865; called by muse, mutect2, varscan2
- KRT26 | c.714del p.N239Tfs*2 | Frame Shift Del (DEL) | VAF 19/146 reads (13%) | catalogued as rs1007245915; called by mutect2, pindel, varscan2
- KRT26 | c.488A>G p.D163G | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV59414413; called by muse, mutect2, varscan2
- KRT78 | c.245dup p.I83Hfs*17 | Frame Shift Ins (INS) | VAF 43/134 reads (32%) | catalogued as rs769740852; called by mutect2, pindel, varscan2
- KRT8 | c.1003A>G p.I335V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as COSV99510020; called by muse, mutect2, varscan2
- KRT9 | c.1840G>A p.G614R | Missense Mutation (SNP) | VAF 43/109 reads (39%) | PolyPhen benign (0.012); catalogued as rs765577453, COSV55852582; called by muse, mutect2, varscan2
- LAD1 | c.976del p.A326Lfs*18 | Frame Shift Del (DEL) | VAF 37/80 reads (46%) | catalogued as COSV66213139; called by mutect2, pindel, varscan2
- LAD1 | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.783); catalogued as rs779029242, COSV66212644; called by muse, mutect2, varscan2
- LAMA1 | c.4721C>T p.A1574V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.197); catalogued as COSV67538658; called by muse, mutect2
- LAMA5 | c.10852C>T p.R3618W | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs764941172, COSV53361869; called by muse, mutect2, varscan2
- LAMC1 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs746664718, COSV51146800; called by muse, mutect2, varscan2
- LANCL1 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52065492; called by muse, mutect2, varscan2
- LARP1 | c.906dup p.T303Hfs*19 (on ENST00000518297 / NM_033551.3; = p.T226Hfs*19 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 13/62 reads (21%) | catalogued as rs769338468; called by mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 19/140 reads (14%) | catalogued as COSV60222740; called by mutect2, varscan2
- LBP | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs140031031; called by muse, mutect2, varscan2
- LDHAL6A | c.420G>A p.V140= | Splice Region (SNP) | VAF 101/265 reads (38%) | catalogued as rs376670096; called by muse, mutect2, varscan2
- LMBRD1 | c.866G>A p.R289H (on ENST00000649011; = p.R267H on NM_018368.4) | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as rs140874824; called by muse, varscan2
- LNX2 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs201989948, COSV60336205; called by muse, mutect2, varscan2
- LOXL3 | c.824del p.G275Afs*5 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as rs746133895; called by mutect2, varscan2
- LPIN1 | c.1606-1G>T p.X536_splice | Splice Site (SNP) | VAF 86/196 reads (44%) | catalogued as COSV56766455; called by muse, mutect2, varscan2
- LRIG3 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as rs1454191094, COSV57865247; called by muse, mutect2, varscan2
- LRP1 | c.2198G>A p.R733Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs905771676, COSV99674354; called by muse, mutect2, varscan2
- LRP1 | c.4505C>A p.A1502D | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54514236; called by muse, mutect2, varscan2
- LRP12 | c.1350T>A p.F450L | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.982); catalogued as COSV52631738, COSV99407617; called by muse, mutect2
- LRP4 | c.1670G>T p.R557L | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66136238; called by muse, mutect2, varscan2
- LRP5 | c.3655C>T p.R1219C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as rs139847357; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC4C | c.394T>G p.F132V | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV53427989; called by muse, mutect2, varscan2
- LRRK1 | c.54G>T p.E18D | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.063); catalogued as COSV52614674; called by muse, mutect2, varscan2
- LRRK2 | c.981A>C p.Q327H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as COSV100110022; called by muse, mutect2
- LSM14A | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV70885205; called by muse, varscan2
- LUC7L2 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs767864698, COSV54926901; called by muse, mutect2, varscan2
- LUC7L3 | c.1165dup p.S389Kfs*2 | Frame Shift Ins (INS) | VAF 60/165 reads (36%) | catalogued as rs1229438198; called by mutect2, varscan2
- LUZP1 | c.1201C>T p.R401* | Nonsense Mutation (SNP) | VAF 29/80 reads (36%) | catalogued as rs1454162875, COSV56501172; called by muse, mutect2, varscan2
- MACF1 | c.19573G>A p.V6525M (on ENST00000372915; = p.V4570M on NM_012090.5) | Missense Mutation (SNP) | VAF 29/82 reads (35%) | catalogued as rs369605640; called by muse, mutect2, varscan2
- MACROH2A2 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64713005; called by muse, mutect2, varscan2
- MAD2L1BP | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.257); catalogued as COSV64665027; called by muse, mutect2, varscan2
- MAGEB3 | c.158A>C p.K53T | Missense Mutation (SNP) | VAF 52/62 reads (84%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.525); catalogued as COSV64397248; called by muse, mutect2, varscan2
- MAML3 | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.041); catalogued as rs371095654; called by muse, mutect2, varscan2
- MAP3K10 | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763193956, COSV53422850; called by muse, mutect2, varscan2
- MAP3K4 | c.472A>G p.K158E | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62334603; called by muse, varscan2
- MAP3K5 | c.3217T>A p.L1073I | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.265); catalogued as COSV62889658; called by muse, mutect2, varscan2
- MAP3K8 | c.212C>A p.P71Q | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV53920251; called by muse, mutect2, varscan2
- MARF1 | c.1697A>C p.K566T | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60024667; called by muse, mutect2, varscan2
- MAST4 | c.3454G>A p.G1152S (on ENST00000403625 / NM_001164664.2; = p.G963S on NM_015183.3) | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99843990; called by muse, mutect2, varscan2
- MATR3 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.586); catalogued as rs749245217, COSV63077691; called by muse, mutect2, varscan2
- MBOAT7 | c.855-3del | Splice Region (DEL) | VAF 10/28 reads (36%) | catalogued as rs756923309; called by mutect2, pindel, varscan2
- MCC | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV56730158; called by muse, mutect2, varscan2
- MCHR2 | c.309dup p.P104Afs*13 | Frame Shift Ins (INS) | VAF 21/82 reads (26%) | catalogued as rs902197100; called by mutect2, pindel, varscan2
- MCM8 | c.837C>A p.S279R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV54514837; called by muse, mutect2, varscan2
- MCMBP | c.1415-1G>T p.X472_splice | Splice Site (SNP) | VAF 13/33 reads (39%) | catalogued as COSV63509419; called by muse, mutect2, varscan2
- MED23 | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV63431633, COSV63433163; called by muse, mutect2, varscan2
- MED25 | c.1482+1G>A p.X494_splice | Splice Site (SNP) | VAF 16/38 reads (42%) | catalogued as rs1568624159, COSV57205160; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEF2B | c.17T>C p.I6T | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV50763168, COSV50764706; called by muse, mutect2, varscan2
- MEOX2 | c.139T>C p.S47P | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56290924; called by muse, mutect2, varscan2
- METTL15 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.041); catalogued as rs763204903, COSV57720630; called by muse, mutect2, varscan2
- MEX3D | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66312013, COSV66312123; called by muse, varscan2
- MFF | c.753-2A>C p.X251_splice | Splice Site (SNP) | VAF 17/83 reads (20%) | catalogued as COSV58825939; called by muse, mutect2, varscan2
- MIA2 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 124/320 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.411); catalogued as rs185291670, COSV54494523; called by muse, mutect2, varscan2
- MICAL1 | c.2872C>T p.R958C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs549625953, COSV57805731; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MIGA2 | c.1631C>T p.T544M | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs751649684, COSV52977259; called by muse, mutect2, varscan2
- MLLT6 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.036); catalogued as rs377118280; called by muse, mutect2, varscan2
- MMP20 | c.359del p.N120Ifs*3 | Frame Shift Del (DEL) | VAF 74/178 reads (42%) | catalogued as rs759614533, CD134338; called by mutect2, varscan2
- MMP24 | c.1784A>G p.D595G | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV55770685; called by muse, mutect2, varscan2
- MOS | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV61336439; called by muse, mutect2, varscan2
- MPO | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs773687000, COSV56564812; called by muse, mutect2, varscan2
- MPV17L2 | c.514A>G p.N172D | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55852906; called by muse, mutect2, varscan2
- MRC2 | c.2069G>A p.R690Q | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs779555505, COSV57640613; called by muse, mutect2, varscan2
- MRE11 | c.1532del p.N511Ifs*13 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs757691558; called by mutect2, varscan2
- MRPL38 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1352525977, COSV53933429; called by muse, mutect2, varscan2
- MRPS14 | c.181A>G p.T61A | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as COSV62880386; called by muse, mutect2, varscan2
- MRPS2 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.035); catalogued as rs771563537, COSV54093515; called by muse, mutect2, varscan2
- MRPS24 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as rs747409691, COSV58182401; called by muse, mutect2, varscan2
- MS4A14 | c.139-1G>T p.X47_splice | Splice Site (SNP) | VAF 48/176 reads (27%) | catalogued as COSV55730063; called by muse, mutect2, varscan2
- MS4A14 | c.1153A>G p.M385V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100280345; called by muse, mutect2, varscan2
- MSRB1 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs760850788, COSV99238214; called by muse, mutect2, varscan2
- MTDH | c.1340del p.K447Rfs*19 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs1286057275; called by mutect2, varscan2
- MTHFR | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV56740731; called by muse, mutect2, varscan2
- MTM1 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 107/141 reads (76%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as rs782468721, COSV60335430; called by muse, mutect2, varscan2
- MTR | c.2830T>A p.W944R | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV63965182; called by muse, mutect2, varscan2
- MTSS2 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs149700961; called by muse, mutect2, varscan2
- MUC13 | c.113C>A p.P38H | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as COSV60701474; called by muse, mutect2, varscan2
- MUC6 | c.4256C>T p.T1419I | Missense Mutation (SNP) | VAF 180/510 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1376229391, COSV70143144; called by muse, mutect2, varscan2
- MUC6 | c.3881C>T p.S1294L | Missense Mutation (SNP) | VAF 182/476 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs746417317, COSV70143146; called by muse, mutect2, varscan2
- MUC6 | c.2758T>C p.S920P | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs778446894, COSV70143149; called by muse, mutect2, varscan2
- MUC6 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs371477008, COSV101424555; called by muse, varscan2
- MUTYH | c.794A>G p.Q265R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV58344322; called by muse, mutect2, varscan2
- MYC | c.847_849del p.S283del (on ENST00000377970; = p.S298del on NM_002467.6) | In Frame Del (DEL) | VAF 34/95 reads (36%) | catalogued as rs1203089442; called by mutect2, pindel, varscan2
- MYH11 | c.2270A>G p.D757G | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55556036; called by muse, mutect2, varscan2
- MYH3 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1555526457, COSV56866060; called by muse, mutect2, varscan2
- MYH7 | c.3994G>A p.A1332T | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs397516198, CM115870, COSV62515921; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.5338G>A p.A1780T | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs200906285, COSV101238758, COSV67964723; called by muse, mutect2, varscan2
- MYL6B | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV52878973; called by muse, mutect2, varscan2
- MYO18A | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs1332710426, COSV62867912; called by muse, mutect2, varscan2
- MYO18B | c.80del p.P27Lfs*32 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as COSV59131252; called by mutect2, pindel
- MYO1G | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as rs774267015, COSV51856660; called by muse, mutect2, varscan2
- MYO3A | c.1573A>C p.N525H | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775770061, COSV56331230; called by muse, mutect2, varscan2
- MYOCD | c.1440del p.S481Pfs*18 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as COSV58513333; called by mutect2, pindel, varscan2
- MYORG | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52626492; called by muse, mutect2, varscan2
- NACA | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV63270413; called by muse, mutect2, varscan2
- NALCN | c.5017C>T p.P1673S | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs1379988455, COSV51941345; called by muse, mutect2, varscan2
- NALCN | c.1059A>C p.E353D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.04); catalogued as rs777751467, COSV51915430, COSV51931323; called by mutect2, varscan2
- NAP1L4 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.738); catalogued as rs754415348, COSV65881305; called by muse, mutect2, varscan2
- NAV3 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV57085530; called by muse, mutect2, varscan2
- NBEA | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1478929230, COSV59791392; called by muse, mutect2, varscan2
- NBEA | c.8458C>T p.P2820S | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV59791433; called by muse, mutect2, varscan2
- NCAM1 | c.927A>T p.K309N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.129); catalogued as COSV57518059; called by muse, mutect2, varscan2
- NDUFS4 | c.422del p.N141Mfs*48 | Frame Shift Del (DEL) | VAF 56/196 reads (29%) | catalogued as rs1323319971; called by mutect2, pindel, varscan2
- NDUFV1 | c.710G>A p.G237D | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV59595756; called by muse, mutect2, varscan2
- NEDD9 | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 38/102 reads (37%) | catalogued as rs1249218736, COSV65221711; called by muse, mutect2, varscan2
- NEU1 | c.313G>T p.G105W | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57667584; called by muse, mutect2, varscan2
- NEURL4 | c.4405C>T p.R1469W | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1333811956, COSV100223259, COSV59750392; called by muse, mutect2, varscan2
- NEXMIF | c.2620T>A p.S874T | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV50037976, COSV50131708; called by muse, mutect2, varscan2
- NIN | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.719); catalogued as COSV55382945; called by muse, mutect2, varscan2
- NINL | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs777310048, COSV54002583, COSV54003728; called by muse, mutect2, varscan2
- NLRP11 | c.2096C>T p.T699M | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.791); catalogued as rs150204832; called by muse, mutect2, varscan2
- NLRP5 | c.1543G>A p.V515M | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.856); catalogued as rs200417782; called by muse, mutect2, varscan2
- NMUR2 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.207); catalogued as rs1326243803, COSV54917555, COSV99677224; called by muse, mutect2, varscan2
- NOL4L | c.396del p.Y133Tfs*20 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | catalogued as rs751187638; called by mutect2, varscan2
- NOMO1 | c.3583C>T p.R1195C | Missense Mutation (SNP) | VAF 40/509 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV99814484; called by muse, mutect2
- NONO | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV52138164; called by muse, mutect2, varscan2
- NOP14 | c.2444C>T p.A815V | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771860782, COSV58625775; called by muse, mutect2, varscan2
- NPFFR1 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs368051663; called by muse, mutect2, varscan2
- NPHP4 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1233700371, COSV65395425; called by muse, mutect2, varscan2
- NPPA | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56740740; called by muse, mutect2, varscan2
- NPR1 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs748008857, COSV64117691; called by muse, mutect2, varscan2
- NPY5R | c.605G>T p.W202L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58452365; called by muse, mutect2, varscan2
- NR4A2 | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100277134; called by muse, mutect2
- NRXN2 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs539415834, COSV55455102; called by muse, mutect2, varscan2
- NT5C1A | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777598956, COSV52494873; called by muse, mutect2, varscan2
- NTRK2 | c.2045G>T p.C682F (on ENST00000323115 / NM_001369534.1; = p.C698F on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52866800; called by muse, mutect2
- NUDT7 | c.53A>G p.D18G | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.164); catalogued as COSV51745737; called by muse, mutect2, varscan2
- NUP214 | c.3760G>A p.A1254T | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs1351459787, COSV63913568; called by muse, mutect2, varscan2
- NXPH2 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.22); catalogued as COSV55641381, COSV55643687; called by muse, mutect2, varscan2
- NYAP2 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1361526299, COSV56007357; called by muse, mutect2, varscan2
- OBSCN | c.19504C>T p.R6502W | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs368739292; called by muse, mutect2, varscan2
- OCEL1 | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52243994; called by muse, mutect2, varscan2
- OLFML3 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs775272671, COSV57436043; called by muse, mutect2, varscan2
- OR1D5 | c.354G>T p.M118I | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101643422; called by muse, mutect2, varscan2
- OR2G6 | c.868T>C p.Y290H | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100598118; called by muse, mutect2, varscan2
- OR2J2 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs775420912, COSV65848084; called by muse, mutect2, varscan2
- OR2M2 | c.940T>G p.L314V | Missense Mutation (SNP) | VAF 63/369 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV62898548; called by muse, mutect2, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs748398423; called by mutect2, varscan2
- OR51B2 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV60916914; called by muse, mutect2, varscan2
- OR52A1 | c.149T>C p.I50T | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV61092594; called by muse, mutect2, varscan2
- OR52N2 | c.356T>C p.L119P | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV57677071; called by muse, mutect2, varscan2
- OTOGL | c.1189C>T p.R397W (on ENST00000547103; = p.R388W on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201300161; called by muse, mutect2, varscan2
- OTX2 | c.98-4G>A | Splice Region (SNP) | VAF 14/33 reads (42%) | catalogued as rs780106127, COSV59765776; called by muse, mutect2, varscan2
- OXCT1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1337801147, COSV52171969; called by muse, mutect2, varscan2
- P2RX1 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.378); catalogued as rs778618357, COSV56654219; called by muse, mutect2, varscan2
- P3H2 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs780816013, COSV60022702; called by muse, mutect2, varscan2
- P4HTM | c.1202G>A p.R401Q (on ENST00000383729 / NM_177939.3; = p.R462Q on NM_177938.2) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.572); catalogued as rs1180777295, COSV59087471; called by muse, mutect2, varscan2
- PACC1 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs373475631; called by muse, mutect2, varscan2
- PACRG | c.576A>C p.Q192H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61306968; called by muse, mutect2, varscan2
- PADI3 | c.1374del p.V459Wfs*17 | Frame Shift Del (DEL) | VAF 37/128 reads (29%) | catalogued as rs747531633; called by mutect2, pindel, varscan2
- PALLD | c.2644C>T p.R882W (on ENST00000505667 / NM_001166108.2; = p.R865W on NM_016081.4) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758884211, COSV99824587; called by mutect2, varscan2
- PANX2 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs1375961758, COSV50294167; called by muse, mutect2
- PAPLN | c.3092C>A p.A1031D (on ENST00000554301; = p.A1004D on NM_173462.4) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as COSV53719106; called by muse, mutect2, varscan2
- PAPPA | c.3182G>A p.G1061D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.448); catalogued as COSV60285169; called by muse, mutect2, varscan2
- PAX3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 71/233 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs145331372; called by muse, mutect2, varscan2
- PBX2 | c.50del p.G17Afs*5 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs773143486; called by mutect2, varscan2
- PBX4 | c.1063del p.Q355Nfs*25 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | catalogued as rs748202447; called by mutect2, pindel, varscan2
- PCDH1 | c.3088C>A p.P1030T | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV54614849; called by muse, mutect2, varscan2
- PCDH11X | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV100011326; called by muse, mutect2, varscan2
- PCDHA11 | c.2297C>T p.T766M | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); catalogued as rs146613275, COSV56510755; called by muse, mutect2, varscan2
- PCDHA12 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 118/253 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.014); catalogued as COSV56510774; called by muse, mutect2, varscan2
- PCDHA13 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as COSV56510782; called by muse, mutect2, varscan2
- PCDHA4 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63540878; called by muse, mutect2, varscan2
- PCDHA6 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65344724; called by muse, mutect2, varscan2
- PCDHA6 | c.1981G>T p.A661S | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.113); catalogued as COSV65342485, COSV65344727; called by muse, mutect2, varscan2
- PCDHA8 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs1416730508, COSV65335361; called by muse, mutect2, varscan2
- PCDHB10 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1262824590, COSV53379818; called by muse, mutect2, varscan2
- PCDHB13 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 63/238 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.319); catalogued as rs782314493, COSV53397511, COSV53399266; called by muse, mutect2, varscan2
- PCDHB15 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as COSV50980407; called by muse, mutect2, varscan2
- PCDHGA11 | c.1145A>G p.Q382R | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.02); catalogued as COSV53964323; called by muse, mutect2, varscan2
- PCK2 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs377444905; called by muse, mutect2, varscan2
- PCNX3 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs996157215, COSV58420142; called by muse, mutect2, varscan2
- PDCD6IP | c.602del p.L201* | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | catalogued as rs781474699; called by mutect2, varscan2
- PDE11A | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1167225025, COSV53697263; called by muse, mutect2, varscan2
- PDE8B | c.602C>A p.A201D | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV53739038; called by muse, mutect2, varscan2
- PDE8B | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as rs772274378, COSV53739050; called by muse, mutect2, varscan2
- PDLIM2 | c.851A>C p.H284P (on ENST00000397760; = p.H534P on NM_021630.6) | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56133274; called by muse, mutect2, varscan2
- PDPR | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 60/499 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99848180; called by muse, mutect2, varscan2
- PDZD2 | c.1747G>A p.V583I | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.87); PolyPhen benign (0.053); catalogued as rs749478209, COSV56860688; called by muse, mutect2, varscan2
- PELP1 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs767650542, COSV52588662; called by muse, mutect2, varscan2
- PFKFB2 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 133/225 reads (59%) | PolyPhen probably damaging (0.995); catalogued as COSV65547087, COSV65548361; called by muse, mutect2, varscan2
- PGAM5 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1383575087, COSV58202315; called by muse, mutect2, varscan2
- PGAP3 | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as rs369388252; called by muse, mutect2, varscan2
- PGD | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as rs1032586290, COSV54621779, COSV54622192; called by muse, mutect2, varscan2
- PGM2L1 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.261); catalogued as rs758479464, COSV99994821; called by muse, mutect2, varscan2
- PGR | c.1655G>A p.S552N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV99678238; called by muse, mutect2
- PHF14 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 26/66 reads (39%) | catalogued as COSV68854082; called by muse, mutect2, varscan2
- PHF2 | c.3269G>A p.R1090Q | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs777779032, COSV63681422; called by muse, mutect2, varscan2
- PHLPP1 | c.4814del p.G1605Vfs*32 | Frame Shift Del (DEL) | VAF 26/87 reads (30%) | catalogued as COSV53023252; called by mutect2, pindel, varscan2
- PHRF1 | c.3274C>T p.R1092W (on ENST00000264555 / NM_001286581.2; = p.R1091W on NM_020901.4) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs762388707, COSV52757028; called by muse, mutect2, varscan2
- PHYHIPL | c.1019T>G p.L340R | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99513689; called by muse, mutect2, varscan2
- PIK3CG | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs1463222028, COSV63246444, COSV63246678; called by muse, mutect2, varscan2
- PIP4K2A | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1253968183, COSV64863591; called by muse, mutect2, varscan2
- PIP4P1 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs776238979, COSV51657477; called by muse, mutect2, varscan2
- PIP4P2 | c.538del p.I180Sfs*21 | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | catalogued as rs1158949501; called by mutect2, varscan2
- PIP5K1A | c.565G>A p.D189N (on ENST00000368888 / NM_001135638.2; = p.D176N on NM_003557.3) | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV62958518; called by muse, mutect2, varscan2
- PITPNM1 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1331904147, COSV62708457; called by muse, mutect2, varscan2
- PIWIL1 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.765); catalogued as rs1264427817, COSV55343930; called by muse, mutect2, varscan2
- PKD1 | c.4057G>A p.G1353S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1474271392, COSV51918074; called by muse, mutect2, varscan2
- PKD1L1 | c.6680G>A p.R2227H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs536655765, COSV56967576; called by muse, mutect2, varscan2
- PKLR | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV61361451; called by muse, mutect2, varscan2
- PKN1 | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.158); catalogued as COSV54398911; called by muse, mutect2, varscan2
- PLBD2 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745951952, COSV55107187; called by muse, mutect2, varscan2
- PLCE1 | c.2041C>T p.H681Y | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV53354368; called by muse, mutect2, varscan2
- PLCH2 | c.3298G>A p.V1100M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.058); catalogued as COSV53944358; called by muse, mutect2, varscan2
- PLEKHG4 | c.3377G>A p.R1126H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs899913556, COSV58573253; called by muse, mutect2, varscan2
- PLEKHH1 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs564069574, COSV61282845; called by muse, mutect2, varscan2
- PLEKHM1 | c.1778G>A p.R593H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372119492; called by muse, mutect2, varscan2
- PLEKHM2 | c.2836C>T p.P946S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV53817282; called by muse, mutect2, varscan2
- PLXNA1 | c.1523C>T p.T508M | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs748424966, COSV52527570; called by muse, mutect2, varscan2
- PLXNA3 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 45/55 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs150180614, COSV63754402; called by muse, mutect2, varscan2
- PMEPA1 | c.624del p.S209Afs*61 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs751873496; called by mutect2, pindel, varscan2
- PMEPA1 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as rs1568959244, COSV55693986; called by muse, mutect2, varscan2
- PNPLA6 | c.1974G>A p.R658= (on ENST00000414982 / NM_001166111.2; = p.R610= on NM_006702.5) | Splice Region (SNP) | VAF 26/70 reads (37%) | catalogued as rs1482457640, COSV55379510; called by muse, mutect2, varscan2
- PNPLA7 | c.3889C>T p.R1297W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1157610670, COSV53002802, COSV99480551; called by muse, mutect2, varscan2
- PODN | c.1387C>T p.R463C (on ENST00000395871; = p.R415C on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs780959803, COSV100439882, COSV57014401; called by muse, mutect2, varscan2
- POLE | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759398253, COSV57682210; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POMT2 | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs751153662, COSV55071645; ClinVar: uncertain significance; called by muse, varscan2
- PPARGC1B | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as rs779270704, COSV58528106; called by muse, mutect2, varscan2
- PPL | c.1362del p.T455Qfs*37 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs753902804; called by mutect2, pindel, varscan2
- PPM1B | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201987533, COSV56767279; called by muse, mutect2, varscan2
- PPME1 | c.960G>T p.L320F | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60296718; called by muse, mutect2, varscan2
- PPP1R12A | c.2651C>T p.T884M | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs764281068, COSV54109167; called by muse, mutect2, varscan2
- PPP6R3 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 29/73 reads (40%) | catalogued as COSV55728568; called by muse, mutect2, varscan2
- PPRC1 | c.4382del p.P1461Hfs*79 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as COSV53386648; called by mutect2, pindel
- PRDM10 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.199); catalogued as rs558494860, COSV62604229; called by muse, mutect2, varscan2
- PRDM4 | c.1616C>A p.P539H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57306091; called by muse, mutect2, varscan2
- PREX2 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.29); catalogued as rs372931548, COSV55776291; called by muse, varscan2
- PREX2 | c.1244T>A p.F415Y | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55776326; called by muse, mutect2, varscan2
- PRICKLE2 | c.2503T>A p.S835T (on ENST00000295902; = p.S779T on NM_198859.4) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV55767137; called by muse, mutect2, varscan2
- PRICKLE2 | c.2170C>T p.R724C (on ENST00000295902; = p.R668C on NM_198859.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs776915714, COSV55767149; called by muse, mutect2, varscan2
- PRKCZ | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs1416861805, COSV66068155; called by muse, mutect2, varscan2
- PRM3 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.181); catalogued as COSV54113351; called by muse, mutect2, varscan2
- PROC | c.1300G>A p.V434I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.053); catalogued as rs766695272, COSV52166372; called by muse, mutect2, varscan2
- PROCA1 | c.655C>T p.R219C (on ENST00000439862 / NM_001366301.1; = p.R191C on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs182342785, COSV56387043; called by muse, mutect2, varscan2
- PROKR2 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs139259742; called by muse, mutect2, varscan2
- PROM2 | c.1504G>A p.V502M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.592); catalogued as rs752633419, COSV58298617; called by muse, mutect2, varscan2
- PSMA8 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 34/84 reads (40%) | catalogued as rs376403017, COSV57603045; called by muse, mutect2, varscan2
- PSMD2 | c.2027G>A p.G676D | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV59530228; called by muse, mutect2, varscan2
- PTCD1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs369260214; called by muse, mutect2, varscan2
- PTCH1 | c.1915T>C p.Y639H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs775023150, COSV59478300; called by muse, varscan2
- PTCH2 | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs769934593, CM091154, COSV64711463; called by muse, mutect2, varscan2
- PTGR2 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs762105231, COSV50866032; called by muse, varscan2
- PTK2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV61783246; called by muse, mutect2, varscan2
- PTK6 | c.340T>C p.Y114H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.397); catalogued as COSV99420520; called by muse, mutect2
- PTPN13 | c.4861C>T p.P1621S (on ENST00000411767 / NM_080683.3; = p.P1602S on NM_006264.3) | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV57409186; called by muse, mutect2, varscan2
- PTPN14 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 145/269 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100872519, COSV65287891; called by muse, mutect2, varscan2
- PTPRA | c.2216C>T p.T739M | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472189220, COSV53782434; called by muse, mutect2, varscan2
- PTPRF | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs777318046, COSV63442800; called by muse, mutect2, varscan2
- PTPRF | c.5363G>A p.R1788Q | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63443741, COSV63444400; called by muse, mutect2
- PTPRZ1 | c.2477C>T p.S826F | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66438322; called by muse, mutect2, varscan2
- PXDNL | c.1331G>A p.G444D | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62489617; called by muse, mutect2, varscan2
- PYGM | c.452T>C p.L151P | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99377048; called by mutect2, varscan2
- QSOX1 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs745681231, COSV62580664; called by muse, mutect2, varscan2
- R3HCC1L | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV54402235; called by muse, mutect2, varscan2
- R3HDM1 | c.3046C>T p.R1016W | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760793686, COSV51525949; called by muse, mutect2, varscan2
- RAB34 | c.555G>T p.Q185H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.183); catalogued as COSV56387060; called by muse, mutect2, varscan2
- RAB5A | c.339T>A p.N113K | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT tolerated (0.84); PolyPhen benign (0.009); catalogued as COSV56084685; called by muse, mutect2, varscan2
- RABL6 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs752387301, COSV61036579; called by muse, mutect2, varscan2
- RARS2 | c.808T>A p.S270T | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65761399; called by muse, mutect2, varscan2
- RASA1 | c.1471A>G p.K491E | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99169778; called by muse, varscan2
- RASL12 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs553620483, COSV54982231; called by muse, mutect2, varscan2
- RBAK | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs1226960477, COSV62331641; called by muse, mutect2, varscan2
- RBM33 | c.2438A>G p.Q813R | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs528583082, COSV56633360; called by mutect2, varscan2
- RCOR1 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51768821; called by muse, mutect2, varscan2
- RECQL5 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53127226; called by muse, mutect2, varscan2
- REEP5 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs138223212; called by muse, mutect2, varscan2
711 further variants in this file (336 protein-altering or splice-affecting, 349 silent, 26 other) are not listed here.
